CCDI case PBCJRT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bf756489-9a15-4b97-b1a7-66af983738a6

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebrum; Age at diagnosis: 14.4 years (5,246 days).

Biospecimens (3 samples)
- Sample 0DTP4W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTP5B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTP5D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
